MMRF case MMRF_1771 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/6bcc0642-12f7-4e7b-93e3-383a7fc3d0c0

Demographics
Sex at birth: male; Race: asian; Ethnicity: not hispanic or latino; Age at index: 58 years; Vital status: Dead; Days to death: 574 days (1.6 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 58.5 years (21,355 days); ISS stage: III; Days to last known disease status: 574 days (1.6 years); Days to last follow up: 574 days (1.6 years).
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 48 days.
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 56 days; Days to treatment end: 111 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 118 days; Days to treatment end: 118 days.
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 133 days; Days to treatment end: 160 days.
   Treatment given: Therapeutic agents: Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 189 days; Days to treatment end: 201 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 203 days; Days to treatment end: 203 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 204 days; Days to treatment end: 204 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 310 days; Days to treatment end: 346 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 364 days; Days to treatment end: 426 days (1.2 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 427 days (1.2 years); Days to treatment end: 455 days (1.2 years).
   Treatment given: Therapeutic agents: Other; Regimen or line of therapy: Second line of therapy; Days to treatment start: 491 days (1.3 years); Days to treatment end: 507 days (1.4 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 574.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 0 (ECOG 3): M Protein 7.17 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 9.03 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.67 mg/dL; Immunoglobulin G 70.8 g/L; Immunoglobulin A 0.52 g/L; Immunoglobulin M 0.32 g/L; Beta 2 Microglobulin 12.9 µg/mL; Lactate Dehydrogenase 6.02 µkat/L; Hemoglobin 5.15 mmol/L; Leukocytes 9.6 ×10⁹/L; Absolute Neutrophil 4.75 ×10⁹/L; Platelets 226 ×10⁹/L; Creatinine 149 µmol/L; Calcium 2.29 mmol/L; Albumin 23 g/L; Total Protein 12.3 g/dL; Glucose 16.2 mmol/L; C-Reactive Protein 3 mg/dL.
- Day 84 (ECOG 2): M Protein 3.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.56 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.7 mg/dL; Immunoglobulin G 7.8 g/L; Immunoglobulin A 0.3 g/L; Immunoglobulin M 0.16 g/L; Hemoglobin 5.64 mmol/L; Leukocytes 7.7 ×10⁹/L; Absolute Neutrophil 6.5 ×10⁹/L; Platelets 146 ×10⁹/L; Creatinine 116 µmol/L; Calcium 2.28 mmol/L; Albumin 40 g/L; Total Protein 6.6 g/dL; Glucose 10.9 mmol/L.
- Day 175 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.53 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.77 mg/dL; Immunoglobulin G 6.5 g/L; Immunoglobulin A 0.3 g/L; Immunoglobulin M 0.2 g/L; Hemoglobin 6.82 mmol/L; Leukocytes 8.6 ×10⁹/L; Absolute Neutrophil 5.4 ×10⁹/L; Platelets 164 ×10⁹/L; Creatinine 112 µmol/L; Calcium 2.4 mmol/L; Albumin 42 g/L; Total Protein 6.3 g/dL; Glucose 11.6 mmol/L.
- Day 280 (ECOG 3): M Protein 1.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.35 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.18 mg/dL; Immunoglobulin G 9 g/L; Immunoglobulin A 1.13 g/L; Immunoglobulin M 0.2 g/L; Lactate Dehydrogenase 3.65 µkat/L; Hemoglobin 5.58 mmol/L; Leukocytes 6.4 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 79 ×10⁹/L; Creatinine 122 µmol/L; Calcium 2.26 mmol/L; Albumin 38 g/L; Total Protein 6.5 g/dL; Glucose 12.7 mmol/L.
- Day 364 (ECOG 1): M Protein 2.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 6.94 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.73 mg/dL; Immunoglobulin G 13.8 g/L; Immunoglobulin A 3.13 g/L; Immunoglobulin M 0.79 g/L; Hemoglobin 6.63 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 92 ×10⁹/L; Creatinine 127 µmol/L; Calcium 2.07 mmol/L; Albumin 36 g/L; Total Protein 7.3 g/dL; Glucose 7 mmol/L.
- Day 455 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 9.35 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 5.48 mg/dL; Immunoglobulin G 16.8 g/L; Immunoglobulin A 2.67 g/L; Immunoglobulin M 1.06 g/L; Hemoglobin 6.94 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 108 ×10⁹/L; Creatinine 141 µmol/L; Calcium 1.84 mmol/L; Albumin 37 g/L; Total Protein 7.7 g/dL; Glucose 8.6 mmol/L.
- Day 497: M Protein 2.9 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.51 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.64 mg/dL; Immunoglobulin G 12.9 g/L; Immunoglobulin A 2.02 g/L; Immunoglobulin M 1.6 g/L; Hemoglobin 7.32 mmol/L; Leukocytes 6.6 ×10⁹/L; Absolute Neutrophil 5.1 ×10⁹/L; Platelets 66 ×10⁹/L; Creatinine 130 µmol/L; Calcium 2.15 mmol/L; Albumin 34 g/L; Total Protein 6.8 g/dL; Glucose 14.1 mmol/L.

Other clinical attributes
- Day 0: Weight: 72 kg; Height: 170 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1771_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 0 days.
- Sample MMRF_1771_1_PB_CD3pos: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 0 days.
